Somatic mutation profile of tumor specimen BA3430D (aliquot aq-BA3430D) from BEATAML1.0 case 2728, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Therapy related myeloid neoplasm; Tissue or organ of origin: Bone marrow; Age at diagnosis: 60.1 years (21,958 days).
Specimen BA3430D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 78431281-b870-4e1c-a6c6-a84404c7376c.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3143D (Solid Tissue Normal), aliquot aq-BA3143D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e5b2fade-8726-4184-b8c9-b3c243779479

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EPB41L3 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 13/159 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs768190757; called by muse, mutect2
